Surgical pathology report (de-identified scan), TCGA case TCGA-HR-A2OH, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Ontario Institute for Cancer Research (OICR), specimen TCGA-HR-A2OH-06A (Metastatic).

Sample Type Tumour Primary

Sample Preparation
Site of Primary (Event)
Site of Tissue
Year of Sample Collection
Age at Sample Collection (yrs)
Sample Comments
Days to Procedure Date
Days to Diagnosis
Type of Procedure
Site of Primary (Histology)
Recurrent Site
Tumour Diameter (mm)
Tumour Depth (mm)
Breslow Technique
Histology
Grade/Differentiation
Pathological T
Pathological N
Clinical M
Histology Comments
banked from left pelvic side wall mass.

Fresh Frozen
Melanoma
Left pelvic side wall mass

1CD-0-3

Melanoma, NOS 8720/3
Site: pelvic wall, NOS C76.3

hw
9/16/11

0
20
Surgical resection
Lower limb and hip
NO
50
999.99000000000001
Unknown
Metastatic melanoma
Grade X (Unknown)
TX
NX
M1,NOS

Site of primary: left dorsal lateral foot. Metastatic tissue

Source: NCI Genomic Data Commons file 03c539ac-7f2a-43bc-9fc9-5441da334288 (TCGA-HR-A2OH.78BAE58A-AA05-4234-AB26-5C3A373741D4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).